Somatic mutation profile of tumor specimen BA3232D (aliquot aq-BA3232D) from BEATAML1.0 case 2714, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 36.0 years (13,150 days).
Specimen BA3232D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 623b25a6-cd3e-4af0-b917-c2f4f1763bb5.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3144D (Solid Tissue Normal), aliquot aq-BA3144D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d71e0f0-926e-4704-ade1-dec649f30790

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBN1 | c.4349G>A p.C1450Y | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1555397419, CM091210; ClinVar: pathogenic; called by muse, varscan2
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 25/221 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
